Gene-level copy-number profile of tumor specimen ALCH-ABZ1-TTP1-A from ALCHEMIST case ALCH-ABZ1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.9 years (25,172 days).
Specimen ALCH-ABZ1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3d9befb1-3bdc-4fd0-aeef-242fe37fc1c2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABZ1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/52b34aff-4c8f-43c7-9c3b-17c346b71b3e

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 115; copy number 1: 30,115; copy number 2: 23,575; copy number 3: 3,228; copy number 4: 577; copy number 5: 658; copy number 6: 107; copy number 8: 1; copy number 9: 9; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 115 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,190,193–90,221,384, 3 genes: IGKV1D-42, IGKV1D-43, IGKV1D-8.
- chr2:218,125,289–218,137,251, 1 gene: CXCR2.
- chr3:15,206,152–15,252,916, 1 gene: CAPN7.
- chr7:99,558,695–99,611,045, 2 genes (within-gene range 0–2): AC005020.2, TMEM225B.
- chr7:105,530,209–105,530,671, 1 gene: AC073073.1.
- chr8:725,188–1,708,476, 6 genes (within-gene range 0–1): AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1.
- chr8:12,356,136–12,400,366, 5 genes: ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A.
- chr8:35,235,475–36,191,194, 6 genes (within-gene range 0–1): UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2.
- chr9:39,072,767–39,810,097, 19 genes: CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P, SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3, FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5, GLIDR, BX664615.1.
- chr9:39,816,599–39,874,562, 1 gene (within-gene range 0–2): BX664615.2.
- chr10:628,638–631,255, 1 gene (within-gene range 0–1): AL358216.1.
- chr11:62,011,751–62,012,602, 1 gene: AP003733.1.
- chr11:66,002,228–66,013,505, 2 genes: BANF1, CST6.
- chr11:71,787,510–71,821,548, 3 genes: FAM86C1P, ALG1L9P, ZNF705E.
- chr12:24,212,421–24,212,495, 1 gene: MIR920.
- chr12:123,536,409–123,536,534, 1 gene: MIR3908.
- chr14:74,552,181–74,560,048, 1 gene (within-gene range 0–2): AC013451.1.
- chr15:22,194,885–22,195,317, 1 gene: IGHV1OR15-4.
- chr15:25,185,631–25,250,940, 36 genes (within-gene range 0–1): SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:59,552,615–59,553,093, 1 gene: AC092754.1.
- chr16:17,192,863–17,194,232, 1 gene (within-gene range 0–2): AC099494.1.
- chr16:34,266,041–34,979,844, 3 genes: BCLAF1P2, AC135776.4, LINC02184.
- chr16:52,934,813–52,935,635, 1 gene: PHBP21.
- chr16:66,908,122–66,918,917, 1 gene: CDH16.
- chr16:85,918,347–85,948,824, 3 genes (within-gene range 0–1): MIR6774, AC092723.5, LINC02132.
- chr17:43,169,880–43,170,077, 1 gene (within-gene range 0–2): AC060780.2.
- chr17:75,818,815–75,820,055, 1 gene (within-gene range 0–2): AC087289.1.
- chr19:1,372,238–1,374,364, 1 gene (within-gene range 0–1): AC004623.1.
- chr19:2,236,824–2,252,073, 3 genes (within-gene range 0–1): SF3A2, AMH, MIR4321.
- chr19:11,996,809–11,996,916, 1 gene (within-gene range 0–1): RNA5SP464.
- chr19:52,797,408–52,857,600, 1 gene (within-gene range 0–1): ZNF28.
- chr19:52,838,010–52,857,649, 1 gene: ZNF468.
- chr21:43,107,942–43,168,646, 1 gene (within-gene range 0–2): AP001631.2.
- chr21:43,159,066–43,172,805, 2 genes: AP001631.1, CRYAA.
- chr22:36,286,847–36,286,907, 1 gene (within-gene range 0–1): MIR6819.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 3,828 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–174,995,308, 1,094 genes, copy number 4–5 (within-gene range 2–5) (broad region; genes not listed).
- chr2:94,575,976–94,604,573, 2 genes, copy number 4: AL845331.2, AL845331.1.
- chr4:4,143,458–4,150,421, 1 gene, copy number 4: UNC93B4.
- chr4:49,502,145–49,589,529, 11 genes, copy number 3: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:58,198–45,895,970, 679 genes, copy number 3 (broad region; genes not listed).
- chr6:28,633,381–28,633,594, 1 gene, copy number 4: AL121932.1.
- chr7:37,032–7,104,482, 171 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr7:7,078,302–51,729,716, 703 genes, copy number 3 (broad region; genes not listed).
- chr7:52,269,437–62,275,678, 159 genes, copy number 3 (broad region; genes not listed).
- chr7:76,959,835–77,043,775, 1 gene, copy number 3 (within-gene range 1–3): DTX2P1-UPK3BP1-PMS2P11.
- chr7:77,011,551–77,043,776, 5 genes, copy number 3 (within-gene range 1–3): PMS2P11, Y_RNA, SPDYE17, PMS2P9, Y_RNA.
- chr7:92,604,921–94,669,695, 33 genes, copy number 3–5: CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2, AC002074.1, COL1A2, RNU6-1328P, CASD1, SGCE, PEG10.
- chr8:47,068,021–47,068,323, 1 gene, copy number 3: RN7SKP32.
- chr9:41,233,755–41,237,557, 2 genes, copy number 5: MIR4477A, RNA5SP530.
- chr9:41,292,887–41,294,125, 1 gene, copy number 3: MYO5BP1.
- chr9:41,340,823–41,355,538, 1 gene, copy number 4: CDRT15P6.
- chr10:97,334,564–97,343,203, 1 gene, copy number 3 (within-gene range 2–3): AL355490.1.
- chr11:47,778,087–47,848,555, 1 gene, copy number 3 (within-gene range 2–3): NUP160.
- chr11:47,820,200–47,905,607, 3 genes, copy number 3: Y_RNA, YPEL5P2, AC023232.1.
- chr11:48,216,810–48,908,946, 25 genes, copy number 3: OR4B1, OR4B2P, OR4X2, OR4X1, OR4S1, OR4C3, OR4C4P, OR4C5, OR4C2P, OR4C10P, OR4C9P, OR4R1P, OR4A47, OR4A48P, OR4A46P, OR4A40P, OR4A43P, OR4A45P, OR4A41P, OR4A42P, OR4A44P, AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:50,409,042–50,422,316, 1 gene, copy number 3: AC024405.1.
- chr11:61,102,489–61,127,852, 1 gene, copy number 3: CD5.
- chr12:24,223,233–34,249,958, 212 genes, copy number 4–9 (within-gene range 0–9) (broad region; genes not listed).
- chr14:20,138,820–42,268,586, 614 genes, copy number 3 (broad region; genes not listed).
- chr15:22,125,511–22,185,402, 6 genes, copy number 5 (within-gene range 1–5): OR4N3P, AC010760.1, RPS8P10, IGHV1OR15-1, IGHV1OR15-3, IGHV4OR15-8.
- chr15:40,735,884–40,755,851, 1 gene, copy number 5: RMDN3.
- chr17:18,450,244–18,475,920, 4 genes, copy number 4: KRT16P4, AL353997.1, AL353997.4, TNPO1P2.
- chr17:18,497,095–18,551,705, 4 genes, copy number 3 (within-gene range 1–3): NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr17:42,536,241–43,153,671, 53 genes, copy number 3: NAGLU, AC067852.1, HSD17B1P1, AC067852.2, HSD17B1, COASY, MLX, PSMC3IP, AC067852.5, RETREG3, AC067852.4, TUBG1, ATP5MGP7, HMGB3P27, TUBG2, PLEKHH3, CCR10, AC100793.2, CNTNAP1, AC100793.3, EZH1, MIR6780A, AC100793.1, AC100793.4, HMGN2P15, RAMP2-AS1, RAMP2, VPS25, WNK4, COA3, CNTD1, BECN1, MIR6781, PSME3, AOC2, AOC3, AOC4P, LINC00671, RNU6-287P, G6PC, AC055866.1, AARSD1, PTGES3L-AARSD1, PTGES3L, RUNDC1, RPL27, IFI35, VAT1, RND2, RPL21P4, NBR2, AC135721.2, AC135721.1.
- chr17:46,372,855–46,487,141, 1 gene, copy number 17: NSFP1.
- chr17:49,202,791–49,369,998, 7 genes, copy number 3: GNGT2, ABI3, PHOSPHO1, FLJ40194, MIR6129, ZNF652, AC091180.2.
- chr17:81,480,523–81,481,570, 1 gene, copy number 4: LINC01971.
- chr19:38,587,641–38,636,955, 3 genes, copy number 3: MAP4K1, AC008649.1, EIF3K.
- chr19:43,064,209–43,083,045, 1 gene, copy number 3 (within-gene range 2–3): PSG2.
- chr20:2,794,074–2,820,284, 4 genes, copy number 3: CPXM1, AL035460.1, C20orf141, TMEM239.
- chr20:5,013,520–5,013,724, 1 gene, copy number 3: AL121890.1.
- chr22:20,689,929–21,014,292, 17 genes, copy number 3 (within-gene range 1–3): POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP.
- chr22:49,933,198–49,934,074, 1 gene, copy number 4: BX539320.1.
- chr22:50,199,090–50,200,837, 1 gene, copy number 8 (within-gene range 2–8): AL022328.4.

Autosomal genes at a single copy (total copy number 1): 30,113. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
